Gene-level copy-number profile of tumor specimen TARGET-10-PARJXW-09A from TARGET case TARGET-10-PARJXW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.8 years (5,413 days).
Specimen TARGET-10-PARJXW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.5b1d0eab-ca56-5114-ba8f-d9cd6d27e3bc.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PARJXW-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 403 have no estimate.
https://portal.gdc.cancer.gov/files/8f3e17d7-ed16-4878-bb76-11fba631431e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 54; copy number 1: 2,999; copy number 2: 57,054; copy number 3: 85; copy number 4: 2; copy number 5: 26.

Homozygous deletions (total copy number 0; autosomes only): 54 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,786,214–152,788,426, 1 gene: LCE1E.
- chr7:38,256,337–38,300,322, 8 genes: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10.
- chr7:142,749,468–142,793,368, 12 genes: PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1.
- chr8:39,314,591–39,522,852, 2 genes (within-gene range 0–2): ADAM5, ADAM3A.
- chr9:21,929,457–25,089,151, 30 genes: ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120.
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 26 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 5 (within-gene range 2–5): AC244205.1.
- chr2:88,857,161–89,129,483, 25 genes, copy number 5: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18.

Autosomal genes at a single copy (total copy number 1): 621. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
